Somatic mutation profile of tumor specimen MP2PRT-PAVNMC-TMP1-A (aliquot MP2PRT-PAVNMC-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVNMC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,461 days).
Specimen MP2PRT-PAVNMC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c31bbf1-50d1-468d-8faa-5b6f61a0030a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVNMC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVNMC-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d79fe474-e41f-404d-a4c9-5bbc52fa4ab8

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 9, Frame Shift Ins 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ENG | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 106/535 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1029569378; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIR2DL4 | c.278G>A p.R93H (on ENST00000396284; = p.R54H on NM_001080770.2) | Missense Mutation (SNP) | VAF 203/487 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs370135620; called by muse, mutect2, varscan2
- KLHL41 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 81/215 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs374653463; called by muse, mutect2, varscan2
- MN1 | c.2335G>A p.G779S | Missense Mutation (SNP) | VAF 80/675 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.268); catalogued as rs1057018621; called by muse, mutect2, varscan2
- NEBL | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 119/296 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs750476653, COSV101008957; called by muse, mutect2, varscan2
- PANX3 | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 14/458 reads (3%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as rs963287592, COSV52511114; called by muse, mutect2
- SCARF1 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 108/594 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs752251326; called by muse, mutect2, varscan2
- ETV6 | c.364_365insCA p.K122Tfs*88 | Frame Shift Ins (INS) | VAF 39/349 reads (11%) | called by mutect2, pindel, varscan2
- GFI1 | c.1190dup p.C398Lfs*104 | Frame Shift Ins (INS) | VAF 205/566 reads (36%) | called by mutect2, pindel, varscan2
- PMS2 | c.167T>C p.L56P | Missense Mutation (SNP) | VAF 64/132 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TULP4 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ARHGEF18 | c.291G>A p.P97= | Silent (SNP) | VAF 37/552 reads (7%) | called by muse, mutect2
- OR52K1 | c.570G>A p.A190= | Silent (SNP) | VAF 24/374 reads (6%) | catalogued as rs760735496, COSV56903428; called by muse, mutect2
